FM case AD8583 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/578d63d9-7c03-4d9c-9df5-992b2c6c8fdc

Female, 58.9 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
